TCGA case TCGA-3L-AA1B — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Albert Einstein Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a94e1279-a975-480a-93e9-7b1ff05cbcbf

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 61.3 years (22,379 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 475 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 28; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 154 days; Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 349, day 475.

Molecular and laboratory tests
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 63.3 kg; Height: 173 cm; BMI: 21.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3L-AA1B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 670 mg.
  Slide TCGA-3L-AA1B-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3L-AA1B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3L-AA1B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 475 days; disease-specific survival: no event (censored), 475 days; disease-free interval: no event (censored), 475 days; progression-free interval: no event (censored), 475 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3L-AA1B-01A-11D-A36W-01): tumor purity 0.39, ploidy 3.49, whole-genome doublings 1.
